Somatic mutation profile of tumor specimen TARGET-40-NAAEDA-01A (aliquot TARGET-40-NAAEDA-01A-01D) from TARGET case TARGET-40-NAAEDA, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 9.5 years (3,464 days).
Specimen TARGET-40-NAAEDA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d6f7cc-268f-4de7-91d1-1843f336b3f8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDA-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cab7cdf3-dc9d-45ed-b54e-f26f6bbfed45

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7076G>A p.G2359E | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63877641; called by muse, mutect2, varscan2
- MASP1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCLO | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TGS1 | c.1732T>G p.S578A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- YLPM1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2
